Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5697, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5697-01A (Primary Tumor).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Right kidney mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right nephrectomy.

FINAL DIAGNOSIS:

KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE
- B. FUHRMAN'S NUCLEAR GRADE IS 2 OF 4
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE
- I. THE ADRENAL GLAND IS UNREMARKABLE
- J. TNM STAGE: pT1a Nx MX.
- K. TNM HISTOLOGIC GRADE = G2.

COMMENT:

A panel of immunohistochemical stains has been performed, which showed the tumor cells to be strongly positive for CD10, and weakly positive for RCC and E-cadherin. Tumor cells are focally positive for cytokeratin 7 and negative for Ber-EP4. A colloidal iron stain was also negative. This staining pattern supports a diagnosis of conventional type renal cell carcinoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Right

TUMOR SITE: Middle

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 4.0 cm

Additional dimensions: 3.5 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT1a

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Uninvolved by tumor

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: Glomerular disease (type): Minimal global glomerulosclerosis

Source: NCI Genomic Data Commons file 2f193afb-0c4a-4237-bff3-7dbe0b02f3d1 (TCGA-B0-5697.AA9FCAA9-CA62-4BC0-AF7A-F7B4009B37F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).